TCGA case TCGA-C5-A1MN — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/287ce10e-31c8-4b10-9858-6e45451dfbe4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Dead; Days to death: 1,245 days (3.4 years).

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 42.4 years (15,499 days); Year of diagnosis: 2007; Method of diagnosis: Biopsy; FIGO stage: Stage IIIB; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, Combination; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Course number: 1; Treatment anatomic sites: Primary Tumor Field.

Follow-up (4 entries)
- Day 1 (preoperative): Days to imaging: 1 day; Imaging type: PET; Imaging result: Positive; Imaging anatomic site: Cervix Uteri; Imaging findings: Parametrium Involvement; Imaging suv: 16.92.
- Day 1 (preoperative): Days to imaging: 1 day; Imaging type: PET; Imaging result: Positive; Imaging findings: Pelvic Lymph Node Involvement.
- Day 875 (post adjuvant therapy): ECOG performance status: 1.
- Days to follow up: 1,245 days (3.4 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Weight: 64 kg; Height: 165 cm; BMI: 23.5.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 25.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A1MN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 110 mg.
  Slide TCGA-C5-A1MN-01A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-C5-A1MN-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A1MN-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 0; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 0; Tobacco smoking history indicator: 2; Performance status timing: Post-Adjuvant Therapy; Tumor response: Complete response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Days to fdg or ct pet performed: 1.
- Fdg or ct pet performed outcomes: Fedpet or ct results: Parametrium Present; Fedpet or ct results: Pelvic Nodes Present.
- Follow-up form: Tumor status: Tumor free; Performance status timing: Post-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Radiation adjuvant indicator: Yes; Brachytherapy type: HDR; Brachytherapy status: Completed as planned; Radiation therapy xrt type: Imrt; New tumor event diagnosis indicator: No.
- Follow-up form, Radiation supplemental: Radiation therapy status: Completed as Planned.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,245 days; disease-specific survival: no event (censored), 1,245 days; disease-free interval: no event (censored), 1,245 days; progression-free interval: no event (censored), 1,245 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A1MN-01A-11D-A14V-01): tumor purity 0.64, ploidy 3.59, whole-genome doublings 1.
